Somatic mutation profile of tumor specimen TCGA-WE-A8ZM-06A (aliquot TCGA-WE-A8ZM-06A-11D-A372-08) from TCGA case TCGA-WE-A8ZM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.8 years (28,047 days).
Specimen TCGA-WE-A8ZM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c26dec31-8088-41ce-bae9-261b0be753ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZM-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZM-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e66b18f2-7280-4669-9102-b7a6ef2a0445

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, Nonsense Mutation 6, Frame Shift Ins 2, Splice Site 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5855G>A p.W1952* (on ENST00000358273 / NM_001042492.3; = p.W1931* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 39/54 reads (72%) | catalogued as rs1567615766, CM062912, COSV62222781; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs761690956, COSV51710451; called by muse, mutect2, varscan2
- ANGEL1 | c.325T>C p.W109R | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99200315; called by muse, mutect2, varscan2
- ANKRD28 | c.2473A>G p.T825A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs765267091, COSV101080304; called by muse, mutect2, varscan2
- ANKRD34B | c.239A>C p.Q80P | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103377; called by muse, mutect2, varscan2
- ANKRD7 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV99500935; called by muse, mutect2, varscan2
- BAG2 | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs980287241, COSV58100055; called by muse, mutect2, varscan2
- C3AR1 | c.193A>C p.T65P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765866542, COSV99368125; called by muse, mutect2, varscan2
- CARF | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.229); catalogued as COSV100247503; called by muse, mutect2, varscan2
- CATSPERB | c.1699A>C p.K567Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.814); catalogued as COSV99830833; called by muse, mutect2, varscan2
- CDH20 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.945); catalogued as COSV53010214; called by muse, mutect2, varscan2
- CDH8 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285043777, COSV54854702; called by muse, mutect2, varscan2
- CDKL5 | c.2416A>T p.K806* | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | catalogued as COSV101184034; called by muse, mutect2, varscan2
- CENPC | c.2402T>A p.L801H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs1374804198, COSV99893542; called by muse, mutect2, varscan2
- COL15A1 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV66646275; called by muse, mutect2, varscan2
- COL25A1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs1405272630, COSV67651454; called by muse, mutect2, varscan2
- DCBLD2 | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as COSV100471437, COSV58788634; called by muse, mutect2, varscan2
- DSP | c.6851G>A p.R2284Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as rs1273566858, COSV65792055; called by muse, mutect2, varscan2
- EXOC6 | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1194999807, COSV99591456; called by muse, mutect2, varscan2
- FAM135B | c.998C>G p.T333S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV99419172; called by muse, mutect2, varscan2
- FBXW9 | c.434G>A p.R145H (on ENST00000587955; = p.R155H on NM_032301.3) | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs1445453198, COSV100790283; called by muse, mutect2, varscan2
- GOLIM4 | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 55/105 reads (52%) | catalogued as COSV100462661; called by muse, mutect2, varscan2
- HDLBP | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100189939; called by muse, mutect2, varscan2
- HIVEP3 | c.3970C>T p.Q1324* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs1179693016, COSV99911524; called by muse, mutect2
- HLA-DOB | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101441036; called by muse, mutect2, varscan2
- HLA-F | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99465659; called by muse, mutect2, varscan2
- INO80 | c.3763A>G p.K1255E | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100731544; called by muse, mutect2, varscan2
- ITGA7 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99144331; called by muse, mutect2, varscan2
- KDR | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs772912254, COSV55760652, COSV55773693; called by muse, mutect2, varscan2
- LAMC1 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51132524, COSV99278997; called by muse, mutect2, varscan2
- LARP4 | c.1433A>G p.D478G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99529039; called by muse, mutect2, varscan2
- LRP1B | c.3463A>C p.K1155Q | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101252879; called by muse, mutect2, varscan2
- MCMDC2 | c.1643A>C p.K548T | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100551702; called by muse, mutect2, varscan2
- MDC1 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV100902582; called by muse, mutect2, varscan2
- MUC16 | c.39461C>T p.S13154F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs750591768, COSV101109610, COSV66692355; called by muse, mutect2, varscan2
- MUC16 | c.26374G>A p.G8792S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV67455410; called by muse, mutect2, varscan2
- MYCBP2 | c.8905C>A p.L2969I (on ENST00000357337; = p.L3007I on NM_015057.5) | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV100629263; called by muse, mutect2, varscan2
- NCOR1 | c.341T>A p.V114D | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV99247518; called by muse, mutect2, varscan2
- OTOF | c.2287G>A p.V763I (on ENST00000272371 / NM_194248.3; = p.V16I on NM_004802.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs138545671; called by muse, mutect2, varscan2
- OTUD4 | c.2098C>T p.R700* (on ENST00000447906 / NM_001366057.1; = p.R635* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs1436089551, COSV101485882; called by muse, mutect2
- PCDHGA10 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99531084; called by muse, mutect2, varscan2
- PEX11A | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 90/554 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100261413, COSV55584677; called by muse, varscan2
- PEX11A | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 103/573 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.828); catalogued as COSV100261415; called by muse, varscan2
- PEX11A | c.384C>G p.Y128* | Nonsense Mutation (SNP) | VAF 41/191 reads (21%) | catalogued as rs1485288607, COSV100261418; called by muse, mutect2, varscan2
- PHACTR3 | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.121); catalogued as COSV100732224; called by muse, mutect2, varscan2
- PRPF8 | c.3343A>T p.T1115S | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV100517145; called by muse, mutect2, varscan2
- PTPN20 | c.918+1G>A p.X306_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as rs1190710603; called by mutect2, varscan2
- RHOT1 | c.1424A>T p.D475V | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV100446906; called by muse, mutect2, varscan2
- RNF32 | c.878G>C p.C293S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100311206; called by muse, mutect2, varscan2
- RNF32 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58734889, COSV58734975; called by muse, mutect2, varscan2
- RPH3A | c.1795G>A p.G599R (on ENST00000389385 / NM_001143854.2; = p.G595R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs779556406, COSV66990024; called by muse, mutect2, varscan2
- RUNX1T1 | c.1019T>G p.M340R (on ENST00000265814 / NM_001198628.1; = p.M313R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV99749599; called by muse, mutect2, varscan2
- S1PR2 | c.59A>C p.Y20S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100495259; called by muse, mutect2, varscan2
- SF3B3 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV100209589; called by muse, mutect2, varscan2
- SMC2 | c.2081A>G p.E694G | Missense Mutation (SNP) | VAF 111/126 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV99658381; called by muse, mutect2, varscan2
- SPEG | c.3492C>A p.S1164R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as COSV100403312; called by muse, mutect2, varscan2
- SPTA1 | c.4976G>A p.R1659Q | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs768976264, COSV100934295, COSV63756889; called by muse, mutect2, varscan2
- SULT1C2 | c.82A>C p.N28H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.418); catalogued as COSV99264990; called by muse, mutect2, varscan2
- TANK | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV99375865; called by muse, mutect2, varscan2
- TAOK2 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763911645, COSV99663889; called by muse, mutect2, varscan2
- ZFP37 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100953189, COSV65287471; called by muse, mutect2, varscan2
- ZNF207 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.062); catalogued as rs1229222433, COSV100340358; called by muse, mutect2, varscan2
- ZNF341 | c.1626T>G p.C542W (on ENST00000375200 / NM_001282935.1; = p.C535W on NM_032819.4) | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100677706; called by muse, mutect2, varscan2
- ZNF534 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99989438; called by muse, mutect2, varscan2
- GGA1 | c.303+3del p.X101_splice | Splice Site (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- MON2 | c.5024dup p.L1675Ffs*21 | Frame Shift Ins (INS) | VAF 40/84 reads (48%) | called by mutect2, pindel, varscan2
- RGS22 | c.1402_1403dup p.L469Tfs*13 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.630C>T p.S210= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs766394158, COSV99898767; called by muse, mutect2, varscan2
- ADGRV1 | c.17052T>C p.S5684= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101315518; called by muse, mutect2, varscan2
- DDB1 | c.2625A>G p.E875= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as rs751748240, COSV100074317; called by muse, mutect2, varscan2
- DDR1 | c.1830C>T p.L610= (on ENST00000324771; = p.L573= on NM_001954.4) | Silent (SNP) | VAF 49/150 reads (33%) | catalogued as rs1355075178, COSV100241014; called by muse, mutect2, varscan2
- GPRIN2 | c.1014G>A p.Q338= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100966295; called by muse, mutect2, varscan2
- HOXB2 | c.285C>T p.F95= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV57488036; called by muse, mutect2, varscan2
- IGKV6D-41 | c.273C>T p.F91= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs867704759; called by muse, mutect2, varscan2
- LRP1 | c.7977C>T p.P2659= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as COSV99674506; called by muse, mutect2, varscan2
- MTUS2 | c.1788G>A p.G596= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV70921985; called by muse, mutect2, varscan2
- PDPR | c.579T>A p.L193= | Silent (SNP) | VAF 76/258 reads (29%) | catalogued as COSV99847788; called by muse, mutect2, varscan2
- POLE | c.1002C>T p.V334= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1555229284, COSV100265416; ClinVar: likely benign; called by muse, mutect2, varscan2
- RALBP1 | c.1161G>A p.T387= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs150447479; called by muse, mutect2, varscan2
- RNF216 | c.2406C>T p.F802= (on ENST00000425013 / NM_207116.3; = p.F859= on NM_207111.4) | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as rs200420546, COSV66289445; called by muse, mutect2, varscan2
- SIN3A | c.3414T>G p.R1138= | Silent (SNP) | VAF 37/424 reads (9%) | catalogued as COSV100845039; called by muse, mutect2
- SLC19A3 | c.579C>G p.P193= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as rs186389781, COSV99295641; called by muse, mutect2, varscan2
- SLC38A8 | c.549T>G p.A183= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100230273; called by muse, mutect2, varscan2
- SPEF2 | c.4221A>G p.T1407= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs1478411010, COSV100288736; called by muse, mutect2, varscan2
- TEX101 | c.718T>C p.L240= (on ENST00000598265 / NM_001130011.3; = p.L258= on NM_031451.4) | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV99494694; called by muse, mutect2, varscan2
- TMEM255A | c.741G>A p.K247= | Silent (SNP) | VAF 37/41 reads (90%) | catalogued as COSV100550192; called by muse, mutect2, varscan2
- TRAV26-2 | c.273C>T p.I91= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- USH1C | c.630G>A p.K210= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99139349; called by muse, mutect2, varscan2
- ZFC3H1 | c.5811T>C p.L1937= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV101110333; called by muse, mutect2, varscan2
- ZFYVE26 | c.3039A>T p.V1013= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV100720097; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.877A>T | RNA (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
